Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAVS, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAVS-01A (Primary Tumor).

ICD-O-3
Carcinoma, hepatocellular
8170/3
Site Liver C22.0
JAN 4/23/14

DIAGNOSIS:

Liver, right, hemihepatectomy:

Hepatocellular carcinoma

- 1) Post-chemoembolization status: absent
- 2) Size of tumor: 10.5x8.0x7.5cm
- 3) Gross type: nodular with perinodal extension
- 4) Satellite nodule: absent
- 5) Histologic type: trabecular and pseudoglandular
- 6) Cell type: classic and clear
- 7) Edmondson and Steiner's histologic grade:
The worst differentiation: 3
The major differentiation: 2
- 8) Fatty change: absent
- 9) Hemorrhage/necrosis: absent
- 10) Tumor necrosis: absent
- 11) Vascular invasion(microscopic): absent
- 12) Capsule formation: partial
- 13) Infiltration of capsule: present
- 14) Septal formation: present
- 15) Involvement of a major branch of the portal vein: absent
- 16) Involvement of a major branch of the hepatic vein: absent
- 17) Bile duct invasion: absent
- 18) Serosal invasion: absent
- 19) Surgical margin: clear resection margin (safety margin: 0.5cm)
- 20) Intrahepatic metastasis: absent
- 21) Multicentric occurrence: absent
- 22) Pathologic stage: AJCC (pT1). (pT2)
- 23) Related biopsy: none
- 24) Additional pathologic findings
- a) Chronic hepatitis, HBV associated
with minimal lobular activity
moderate porto-periportal activity
portal fibrosis
- b) Cirrhosis: absent
- c) Dysplasia: absent

Gallbladder, cholecystectomy:

Chronic cholecystitis
with cholesterol polyp

Source: NCI Genomic Data Commons file 7d0d55a2-5060-44a6-b623-a60f065b0231 (TCGA-DD-AAVS.5F714C34-BB01-49D1-B41C-C64DE8D0EC0E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).